Somatic mutation profile of tumor specimen TCGA-HC-A6AS-01A (aliquot TCGA-HC-A6AS-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AS, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.3 years (25,661 days).
Specimen TCGA-HC-A6AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 363f10ef-e934-4212-bde5-fc45d6ac4a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AS-10A (Blood Derived Normal), aliquot TCGA-HC-A6AS-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/299c28ce-0fcd-48d2-8828-59d32c8a8914

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARPP21 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs376713321, COSV51793709; called by muse, mutect2
- ATP2B2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59504164; called by muse, mutect2
- CNGA4 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 21/141 reads (15%) | catalogued as rs1470588599, COSV66006636; called by muse, mutect2, varscan2
- COL12A1 | c.8225C>T p.T2742I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV59403449; called by muse, mutect2
- CREB3L2 | c.1270+2T>C p.X424_splice | Splice Site (SNP) | VAF 23/177 reads (13%) | catalogued as COSV57798414; called by muse, mutect2, varscan2
- EGFLAM | c.2136T>A p.D712E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV59312105; called by muse, mutect2, varscan2
- FNDC1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1384956388, COSV51933311; called by muse, mutect2, varscan2
- GFPT2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs529762937, COSV53811067; called by muse, mutect2, varscan2
- H3C7 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV55100569; called by muse, mutect2, varscan2
- LDB2 | c.531T>C p.H177= | Splice Region (SNP) | VAF 13/95 reads (14%) | catalogued as rs759681472, COSV58777154; called by muse, mutect2, varscan2
- NDUFV1 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100295285, COSV59596184; called by muse, mutect2
- PCNT | c.6457A>C p.N2153H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV64031519; called by muse, mutect2, varscan2
- PSME1 | c.163A>G p.S55G | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as COSV52825336; called by muse, mutect2
- RPS27A | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV55053199; called by muse, mutect2, varscan2
- TPCN2 | c.339C>A p.Y113* | Nonsense Mutation (SNP) | VAF 23/187 reads (12%) | catalogued as COSV53732400; called by muse, mutect2, varscan2
- TRIM22 | c.1376T>G p.V459G | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66091428; called by muse, mutect2
- TRUB1 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs749367290, COSV53930709; called by muse, mutect2
- UROC1 | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as rs763877001, COSV52037090; called by muse, mutect2, varscan2
- ZNF583 | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52400915, COSV52404054; called by muse, mutect2, varscan2
- H4C8 | c.138A>C p.R46= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV56805450; called by muse, mutect2
- PDIK1L | c.1008T>C p.D336= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1244720941, COSV65322889; called by muse, mutect2
- TJP1 | c.801G>A p.T267= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs764484998, COSV62039463; called by muse, mutect2, varscan2
